Somatic mutation profile of tumor specimen TARGET-50-PADZUB-01A (aliquot TARGET-50-PADZUB-01A-01D) from TARGET case TARGET-50-PADZUB, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 15.2 years (5,557 days).
Specimen TARGET-50-PADZUB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86aa6190-88fc-40fb-9bfa-669298143a5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PADZUB-10A (Blood Derived Normal), aliquot TARGET-50-PADZUB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dffe8832-c84d-4cb8-8c2c-bfc710fbac2f

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV61373541; called by muse, mutect2, varscan2
- BCORL1 | c.3268C>T p.R1090* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV54389244; called by muse, mutect2, varscan2
- DMXL1 | c.5812G>C p.G1938R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.154); catalogued as rs144486951; called by muse, mutect2
- NCAPG2 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV51987072; called by muse, mutect2, varscan2
- ARRB1 | c.1103A>C p.N368T | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPBD1 | c.218_220del p.P73del | In Frame Del (DEL) | VAF 8/30 reads (27%) | called by pindel, varscan2
